Somatic mutation profile of tumor specimen BA2902D (aliquot aq-BA2902D) from BEATAML1.0 case 2144, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.4 years (30,461 days).
Specimen BA2902D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcabba1c-b419-4726-adc8-c93cd7407f9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2252D (Solid Tissue Normal), aliquot aq-BA2252D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e45df8f1-d940-4eb0-80ae-a90b0f1aaf34

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 3, Silent 3, Splice Site 2, Intron 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHA9 | c.1461C>G p.N487K | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554143536, COSV65323655; called by muse, mutect2
- SYCP1 | c.1703C>G p.T568R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65698147; called by muse, mutect2, varscan2
- ABLIM1 | c.2107C>G p.R703G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by mutect2, varscan2
- CYP2S1 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- MED24 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- POLR3B | c.3024C>G p.Y1008* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- SBNO1 | c.551-1G>T p.X184_splice (on ENST00000420886; = p.X183_splice on NM_018183.5) | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SPATA1 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | called by mutect2, varscan2
- SPTBN5 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.057); called by muse, mutect2
- TNKS1BP1 | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.215); called by muse, mutect2
- ZRSR2 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- ADD3 | c.381A>G p.T127= | Silent (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- MUC12 | c.291G>C p.V97= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ZFP42 | c.459G>T p.P153= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV58819509; called by muse, mutect2, varscan2
- GGT1 | chr22:24633441 ins GG | 3'Flank (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel*
- HOXA3 | c.-389-3024G>C | Intron (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- UPF3B | c.-1C>G | 5'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
